Somatic mutation profile of tumor specimen TCGA-13-0911-01A (aliquot TCGA-13-0911-01A-01W-0420-08) from TCGA case TCGA-13-0911, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,276 days).
Specimen TCGA-13-0911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db271069-15ed-44df-b507-de0e81579f01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0911-10A (Blood Derived Normal), aliquot TCGA-13-0911-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8239c67a-95f8-4191-9bd0-5d7f5d57f33c

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as rs369405118; called by muse, mutect2, varscan2
- ARL5B | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1192435103, COSV66011189; called by muse, mutect2, varscan2
- ATP6AP1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 142/254 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV63895611; called by muse, mutect2, varscan2
- CAMTA1 | c.2999A>C p.K1000T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV57897905; called by muse, mutect2, varscan2
- CD47 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 242/1579 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.729); catalogued as COSV62527050; called by muse, mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs773511514; called by mutect2, varscan2
- FSCB | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV61217805; called by muse, mutect2, varscan2
- GPR35 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV60577118; called by muse, mutect2, varscan2
- LCTL | c.857G>C p.C286S | Missense Mutation (SNP) | VAF 159/280 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV58421946; called by muse, mutect2, varscan2
- LRP2 | c.7183T>C p.S2395P | Missense Mutation (SNP) | VAF 230/554 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV55551263; called by muse, mutect2, varscan2
- MAGI2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 31/516 reads (6%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.766); catalogued as rs759667457, COSV62678117; called by muse, mutect2
- MS4A3 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53935897, COSV53936514; called by muse, mutect2, varscan2
- NETO1 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 39/192 reads (20%) | catalogued as COSV100199876, COSV55005785; called by muse, mutect2, varscan2
- OR1I1 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs760374428, COSV52917827; called by muse, mutect2, varscan2
- PCDHGA2 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV53938063, COSV99538431; called by muse, mutect2, varscan2
- RETREG1 | c.713T>C p.I238T (on ENST00000306320 / NM_001034850.2; = p.I97T on NM_019000.4) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs991974394, COSV60448259; called by muse, mutect2, varscan2
- RPS6KB2 | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs964559937, COSV57049530; called by muse, mutect2, varscan2
- SOSTDC1 | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV61049258; called by muse, mutect2, varscan2
- TOP3B | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV64117159; called by muse, mutect2, varscan2
- LEMD3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.015); called by muse, mutect2
- OFD1 | c.2745_2746del p.Y916Sfs*7 | Frame Shift Del (DEL) | VAF 177/1006 reads (18%) | called by mutect2, pindel, varscan2
- TP53 | c.127_131del p.L43Afs*7 | Frame Shift Del (DEL) | VAF 641/1218 reads (53%) | called by mutect2, pindel, varscan2
- CAMKV | c.354G>A p.S118= | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as rs142554452; called by muse, mutect2, varscan2
- LEMD3 | c.1020G>A p.A340= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- PEG3 | c.993A>G p.A331= | Silent (SNP) | VAF 118/462 reads (26%) | catalogued as COSV55632041; called by muse, mutect2, varscan2
- RAP1GDS1 | c.741T>C p.V247= (on ENST00000408927 / NM_001100427.2; = p.V248= on NM_021159.5) | Silent (SNP) | VAF 118/228 reads (52%) | catalogued as COSV52786832; called by muse, mutect2, varscan2
- SALL4 | c.591C>T p.S197= | Silent (SNP) | VAF 54/462 reads (12%) | catalogued as rs764301551; called by mutect2, varscan2
